CCDI case PBBPHE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e98fa92b-c3b1-4627-81ee-3f2f87ce7048

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,096 days).

Biospecimens (3 samples)
- Sample 0DE5N9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE5OP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE5R3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
